TCGA case TCGA-B6-A3ZX — Breast Invasive Carcinoma (TCGA-BRCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast; Tissue source site: Duke. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/9434687a-197c-4959-b6b8-9c05f1dd7f53

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 50 years; Vital status: Dead; Days to death: 1,152 days (3.2 years).

Diagnoses (2)
1. Infiltrating duct and lobular carcinoma (the primary disease): ICD-O-3 morphology code: 8522/3; ICD-10 code: C50.9; Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 50.5 years (18,434 days); Year of diagnosis: 2007; Method of diagnosis: Core Biopsy; AJCC staging edition: 6th; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Bone, NOS / Breast, Left Upper Inner.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 1; Lymph nodes tested: 7; Micrometastasis present: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Doxorubicin; Days to treatment start: 91 days; Days to treatment end: 147 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Days to treatment start: 148 days; Days to treatment end: 225 days.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 354 days; Days to treatment end: 386 days (1.1 years); Treatment dose: 200 cGy; Number of fractions: 25; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Surgery, NOS; Treatment intent type: Re-Excision; Initial disease status: Initial Diagnosis; Margin status: Uninvolved; Treatment anatomic sites: Breast.
   Treatment given: Treatment type: Surgery, NOS; Treatment intent type: First-Line Therapy; Initial disease status: Initial Diagnosis; Margin status: Indeterminate; Treatment anatomic sites: Breast.
2. Metastasis of diagnosis 1 (Infiltrating duct and lobular carcinoma), site: Bone, NOS. Age at diagnosis: 53.2 years (19,428 days); Days to diagnosis: 994 days (2.7 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 1,096 days (3.0 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Surgery, NOS, for progressive disease.

Follow-up (3 entries)
- Day 994 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Bone, NOS; Days to progression: 994 days (2.7 years).
- Days to follow up: 1,132 days (3.1 years); Disease response: With Tumor.
- Days to follow up: 1,152 days (3.2 years); Disease response: With Tumor.

Molecular and laboratory tests
- ERBB2 (IHC): Negative; Staining intensity value: 1+; Test value range: <10%.
- ESR1 (IHC): Negative; Staining intensity scale: 4 Point Scale; Staining intensity value: 1+; Test value range: <10%.
- PGR (IHC): Negative; Staining intensity scale: 4 Point Scale; Staining intensity value: 1+; Test value range: <10%.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-B6-A3ZX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 5 mg.
  Slide TCGA-B6-A3ZX-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-B6-A3ZX-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Tumor status: With tumor; Lymph nodes examined: Yes; Axillary staging method: Axillary lymph node dissection alone; Surgical procedure first: Lumpectomy; Surgery for positive margins: Lumpectomy; Histologic diagnosis: Mixed Histology (please specify); Histologic diagnosis other: ductal and lobular; Micromet detection by IHC: No; Er IHC score: 1+; Her2 IHC score: 1+; Margin status: Close; Method initial path diagnosis: Core needle biopsy; Her2 IHC percent positive: <10%; Prospective collection: No; Retrospective collection: Yes; Er status IHC Percent Positive: <10%; Pr status IHC percent positive: <10%.
- Anatomic neoplasm subdivisions: Anatomic organ subdivision: Left Upper Inner Quadrant.
- First nonlymph node metastasis anatomic sites: Metastasis site: Bone.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,152 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,152 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 994 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-B6-A3ZX-01A-11D-A238-01): tumor purity 0.13, ploidy 3.08, whole-genome doublings 1.
